Somatic mutation profile of tumor specimen HCM-BROD-0118-C16-06A (aliquot HCM-BROD-0118-C16-06A-01D-A79L-36) from HCMI case HCM-BROD-0118-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Tumor grade: GX; Age at diagnosis: 46.0 years (16,790 days).
Specimen HCM-BROD-0118-C16-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a74201d4-c553-4e4c-8bb3-fea0abece34e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0118-C16-10B (Blood Derived Normal), aliquot HCM-BROD-0118-C16-10B-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a82b9a4a-ca94-4f49-ba64-9f430001b92d

The open-access MAF lists 152 somatic variants for this specimen: 98 protein-altering or splice-affecting, 46 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 46, Nonsense Mutation 8, Frame Shift Ins 4, Frame Shift Del 4, Intron 3, In Frame Ins 2, Splice Region 2, 5'Flank 2, 5'UTR 2, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 38/220 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC105001.2 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs377715499; called by muse, mutect2, varscan2
- ARHGAP30 | c.2782C>G p.L928V (on ENST00000368013 / NM_001025598.2; = p.L717V on NM_181720.3) | Missense Mutation (SNP) | VAF 83/480 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV63514846; called by muse, mutect2, varscan2
- ATP2B3 | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 161/310 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782151825, COSV54845659; called by muse, mutect2, varscan2
- CACNA1G | c.2326G>C p.E776Q | Missense Mutation (SNP) | VAF 17/283 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61721003; called by muse, mutect2
- CD248 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 80/394 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.365); catalogued as rs991947564; called by muse, mutect2, varscan2
- CEP295NL | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 67/293 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs367913374; called by muse, mutect2, varscan2
- COL2A1 | c.2410G>A p.G804R | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100475320, COSV61535514; called by muse, mutect2, varscan2
- CPEB1 | c.797G>A p.R266H (on ENST00000617958; = p.R206H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs1361276650; called by muse, mutect2, varscan2
- CTBP2 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 58/321 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); catalogued as rs781768901; called by muse, mutect2, varscan2
- DCC | c.1153T>G p.L385V | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59087954; called by muse, mutect2, varscan2
- DERA | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs774189773; called by muse, mutect2, varscan2
- DHX38 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 43/334 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs369133069; called by muse, mutect2, varscan2
- DSCAM | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 58/330 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs577827734, COSV68630908; called by muse, mutect2, varscan2
- ERICH3 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.217); catalogued as rs1393569433, COSV58599461; called by muse, mutect2, varscan2
- GAB3 | c.919C>G p.P307A | Missense Mutation (SNP) | VAF 76/331 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782191474; called by muse, mutect2, varscan2
- GAN | c.428A>G p.H143R | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1330501647; called by muse, mutect2, varscan2
- GPAT3 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.753); catalogued as rs760068026; called by muse, mutect2, varscan2
- H3C11 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV58899154; called by muse, mutect2, varscan2
- HDLBP | c.2671C>A p.P891T | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV100190921; called by muse, mutect2, varscan2
- ITGAD | c.2857C>T p.R953C | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs182955563, COSV54932632, COSV99791380; called by muse, mutect2, varscan2
- KRTAP3-2 | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 66/2670 reads (2%) | catalogued as rs747334399; called by muse, mutect2
- LCT | c.2972C>T p.S991F | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as rs758837934, COSV51553686; called by muse, mutect2, varscan2
- LRRC63 | c.487C>G p.P163A | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.117); catalogued as rs760333643; called by muse, mutect2, varscan2
- NEK4 | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 36/192 reads (19%) | catalogued as rs771482582, COSV51780821; called by muse, mutect2, varscan2
- NT5DC1 | c.609dup p.W204Mfs*21 | Frame Shift Ins (INS) | VAF 28/220 reads (13%) | catalogued as rs1333815692; called by mutect2, pindel, varscan2
- P3H4 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 96/3674 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1175435542; called by muse, mutect2
- PRICKLE1 | c.2396C>G p.S799C | Missense Mutation (SNP) | VAF 65/355 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV58210761; called by muse, mutect2, varscan2
- PTPRD | c.2332G>C p.D778H | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.863); catalogued as COSV61981297; called by muse, mutect2, varscan2
- SHANK3 | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 52/370 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1448376623, COSV99436944; called by muse, mutect2, varscan2
- SIDT1 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.974); catalogued as rs779212591, COSV53507931; called by muse, mutect2, varscan2
- SMPDL3B | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs144852835; called by muse, mutect2, varscan2
- SPART | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 47/324 reads (15%) | catalogued as rs776372801; called by muse, mutect2, varscan2
- THSD7B | c.3236G>A p.R1079K (on ENST00000272643; = p.R1077K on NM_001316349.2) | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs1423425617; called by muse, mutect2, varscan2
- TTC30A | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 73/343 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1448523643, COSV53697385, COSV99610615, COSV99610790; called by muse, mutect2, varscan2
- VANGL2 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 57/403 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs781038004, COSV63604080; called by muse, mutect2, varscan2
- WDR38 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 60/336 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1424090984; called by muse, mutect2, varscan2
- WDR81 | c.4943C>T p.S1648L (on ENST00000409644 / NM_001163809.2; = p.S597L on NM_152348.4) | Missense Mutation (SNP) | VAF 97/443 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs781192587, COSV58488341; called by muse, mutect2, varscan2
- ZBP1 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs765287829, COSV100472960; called by muse, varscan2
- ZNF223 | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.724); catalogued as rs759055520; called by muse, mutect2, varscan2
- ZNF596 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs148785316; called by muse, mutect2, varscan2
- ARVCF | c.1753G>C p.E585Q | Missense Mutation (SNP) | VAF 66/461 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC20B | c.665A>C p.K222T | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- CFH | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 75/244 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHST13 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 67/368 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- CNTN3 | c.101A>C p.N34T | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- COL4A1 | c.1808dup p.G604Wfs*13 | Frame Shift Ins (INS) | VAF 56/517 reads (11%) | called by mutect2, pindel, varscan2
- CPNE9 | c.753G>C p.Q251H | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CSMD1 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CTNND1 | c.1180T>C p.C394R | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- DCAF8 | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH3 | c.2341C>T p.Q781* | Nonsense Mutation (SNP) | VAF 37/203 reads (18%) | called by muse, mutect2, varscan2
- DYTN | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DZIP1 | c.1625_1626del p.R542Nfs*17 (on ENST00000347108; = p.R523Nfs*17 on NM_014934.5) | Frame Shift Del (DEL) | VAF 44/391 reads (11%) | called by mutect2, pindel, varscan2
- EQTN | c.533_540del p.L178Qfs*22 | Frame Shift Del (DEL) | VAF 65/284 reads (23%) | called by pindel, varscan2
- EXOC6B | c.2247T>G p.Y749* | Nonsense Mutation (SNP) | VAF 43/248 reads (17%) | called by muse, mutect2, varscan2
- FECH | c.192G>A p.K64= | Splice Region (SNP) | VAF 31/190 reads (16%) | called by muse, mutect2, varscan2
- FNDC3A | c.1666G>A p.E556K (on ENST00000492622 / NM_001079673.2; = p.E500K on NM_014923.5) | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FNTA | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 34/162 reads (21%) | called by muse, mutect2, varscan2
- FOCAD | c.2606C>T p.S869L | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPC6 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- IQCH | c.3037G>C p.E1013Q | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- LARGE1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.319-1_319insCAA p.L106_I107insQ | In Frame Ins (INS) | VAF 45/370 reads (12%) | called by muse*, mutect2, varscan2*
- MAGI2 | c.4256del p.P1419Rfs*55 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- MAGI2 | c.2334T>G p.D778E | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MANF | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP2K7 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 77/202 reads (38%) | called by muse, mutect2, varscan2
- MTHFD1L | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- NAGPA | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 88/444 reads (20%) | PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NELFB | c.1823A>C p.Q608P | Missense Mutation (SNP) | VAF 66/388 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLGN1 | c.2428C>T p.H810Y | Missense Mutation (SNP) | VAF 44/309 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- NUDT14 | c.426C>T p.Y142= | Splice Region (SNP) | VAF 37/205 reads (18%) | called by muse, mutect2, varscan2
- NUP85 | c.889_895dup p.E299Afs*7 | Frame Shift Ins (INS) | VAF 23/174 reads (13%) | called by mutect2, varscan2
- PCSK9 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIK3C2G | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 39/258 reads (15%) | called by muse, mutect2, varscan2
- PIP5K1B | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PPIL2 | c.1406_1422del p.G469Dfs*72 (on ENST00000335025 / NM_148175.3; = p.G469Dfs*105 on NM_014337.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 46/417 reads (11%) | called by mutect2, pindel
- RLF | c.2918A>G p.K973R | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- RNPC3 | c.1366G>C p.D456H | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SEC62 | c.399G>C p.E133D | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SEMA3B | c.1164C>G p.F388L | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SERPINB9 | c.731A>G p.K244R | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SERPINE2 | c.295_297dup p.I99dup | In Frame Ins (INS) | VAF 32/232 reads (14%) | called by mutect2, pindel, varscan2
- SETDB2 | c.1962T>G p.C654W | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMARCA1 | c.2097+1G>T p.X699_splice | Splice Site (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- SMC6 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- SNTB1 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 99/411 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SUDS3 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 49/269 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SYNE1 | c.15736G>A p.E5246K (on ENST00000367255 / NM_182961.4; = p.E5175K on NM_033071.3) | Missense Mutation (SNP) | VAF 68/339 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- TFAP2E | c.306_307dup p.P103Rfs*76 | Frame Shift Ins (INS) | VAF 69/381 reads (18%) | called by mutect2, pindel, varscan2
- TIGD5 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 47/467 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2
- TLN2 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TMC4 | c.675C>G p.F225L (on ENST00000617472 / NM_001145303.3; = p.F219L on NM_144686.4) | Missense Mutation (SNP) | VAF 52/407 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TRAF6 | c.652T>A p.C218S | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUBB | c.969G>T p.M323I | Missense Mutation (SNP) | VAF 78/458 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); called by mutect2, varscan2
- USP11 | c.1948G>T p.D650Y (on ENST00000218348; = p.D607Y on NM_001371072.1) | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- ZNF880 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- BPTF | c.108C>T p.I36= | Silent (SNP) | VAF 66/271 reads (24%) | called by muse, mutect2, varscan2
- BST2 | c.102C>T p.I34= | Silent (SNP) | VAF 53/296 reads (18%) | catalogued as rs1408717756, COSV53089403; called by muse, mutect2, varscan2
- C2 | c.588C>G p.V196= | Silent (SNP) | VAF 74/450 reads (16%) | catalogued as COSV54960877; called by muse, mutect2, varscan2
- CALN1 | c.645G>A p.R215= (on ENST00000329008 / NM_001017440.3; = p.R257= on NM_031468.4) | Silent (SNP) | VAF 31/172 reads (18%) | catalogued as COSV61123899; called by muse, mutect2, varscan2
- CAPN5 | c.1476C>T p.I492= (on ENST00000456580; = p.I452= on NM_004055.5) | Silent (SNP) | VAF 76/430 reads (18%) | called by muse, mutect2, varscan2
- COL16A1 | c.3219C>G p.L1073= | Silent (SNP) | VAF 56/271 reads (21%) | called by muse, mutect2, varscan2
- CSMD1 | c.3081C>T p.F1027= (on ENST00000520002; = p.F1026= on NM_033225.6) | Silent (SNP) | VAF 39/263 reads (15%) | catalogued as COSV59288719; called by muse, mutect2, varscan2
- CUBN | c.195C>T p.T65= | Silent (SNP) | VAF 50/331 reads (15%) | catalogued as rs373954380; called by muse, mutect2
- DACT1 | c.1722G>A p.R574= | Silent (SNP) | VAF 44/326 reads (13%) | called by muse, mutect2, varscan2
- DNAH17 | c.4374C>T p.N1458= | Silent (SNP) | VAF 58/315 reads (18%) | called by muse, mutect2, varscan2
- DNM1 | c.69C>T p.I23= | Silent (SNP) | VAF 78/459 reads (17%) | catalogued as rs1260683636; called by muse, mutect2, varscan2
- DOT1L | c.759G>A p.L253= | Silent (SNP) | VAF 16/332 reads (5%) | called by muse, mutect2
- FAM120C | c.135G>A p.P45= | Silent (SNP) | VAF 110/271 reads (41%) | called by muse, varscan2
- FAT3 | c.7092C>T p.V2364= | Silent (SNP) | VAF 45/242 reads (19%) | called by muse, mutect2, varscan2
- FAT4 | c.5796C>T p.F1932= | Silent (SNP) | VAF 27/195 reads (14%) | catalogued as COSV100628248, COSV100629757; called by muse, mutect2, varscan2
- FBXO45 | c.342C>T p.F114= | Silent (SNP) | VAF 22/266 reads (8%) | catalogued as rs767596797; called by muse, mutect2
- GRB7 | c.1230C>G p.L410= | Silent (SNP) | VAF 54/1892 reads (3%) | called by muse, mutect2
- HMCN2 | c.13656C>A p.G4552= | Silent (SNP) | VAF 57/333 reads (17%) | catalogued as rs148355972; called by mutect2, varscan2
- ILVBL | c.1767C>A p.L589= | Silent (SNP) | VAF 62/355 reads (17%) | catalogued as rs1429240647, COSV54621281, COSV99655084; called by muse, mutect2, varscan2
- IRAK1BP1 | c.72G>A p.E24= | Silent (SNP) | VAF 58/334 reads (17%) | catalogued as rs1467655410, COSV64047854; called by muse, mutect2, varscan2
- KLHL29 | c.2037C>T p.L679= | Silent (SNP) | VAF 46/317 reads (15%) | catalogued as rs866239614, COSV56026124; called by muse, mutect2, varscan2
- KMT2B | c.5287C>T p.L1763= | Silent (SNP) | VAF 24/196 reads (12%) | called by muse, mutect2, varscan2
- LRBA | c.7200A>G p.S2400= | Silent (SNP) | VAF 30/158 reads (19%) | catalogued as rs1456691130, COSV63953568; called by muse, mutect2, varscan2
- NEXMIF | c.3441C>T p.V1147= | Silent (SNP) | VAF 54/176 reads (31%) | called by muse, mutect2, varscan2
- NUP188 | c.78G>C p.L26= | Silent (SNP) | VAF 26/213 reads (12%) | catalogued as rs112594279, COSV65361459, COSV65362125; called by muse, mutect2, varscan2
- OR7E24 | c.36C>G p.L12= | Silent (SNP) | VAF 25/171 reads (15%) | called by muse, mutect2, varscan2
- PCLO | c.2544C>T p.P848= | Silent (SNP) | VAF 54/289 reads (19%) | catalogued as rs375555006; called by muse, mutect2, varscan2
- PKHD1 | c.10614C>T p.I3538= | Silent (SNP) | VAF 32/192 reads (17%) | catalogued as rs1348569812; called by muse, mutect2, varscan2
- PKP1 | c.1995G>C p.V665= | Silent (SNP) | VAF 18/426 reads (4%) | called by muse, mutect2
- PLEKHS1 | c.1110G>C p.L370= | Silent (SNP) | VAF 33/305 reads (11%) | called by muse, mutect2, varscan2
- POGK | c.1239G>A p.P413= | Silent (SNP) | VAF 56/361 reads (16%) | catalogued as rs1459883803; called by muse, mutect2, varscan2
- PPFIA3 | c.1155C>G p.L385= | Silent (SNP) | VAF 42/287 reads (15%) | called by muse, mutect2, varscan2
- PSMC1 | c.489G>A p.L163= | Silent (SNP) | VAF 27/173 reads (16%) | called by muse, mutect2, varscan2
- RFX3 | c.384C>T p.I128= | Silent (SNP) | VAF 41/194 reads (21%) | called by muse, mutect2, varscan2
- RGPD3 | c.3264C>G p.L1088= | Silent (SNP) | VAF 74/408 reads (18%) | called by muse, mutect2, varscan2
- RIMS1 | c.4077C>T p.L1359= | Silent (SNP) | VAF 59/339 reads (17%) | called by muse, mutect2, varscan2
- SLC15A5 | c.1017G>C p.L339= | Silent (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- SLC20A2 | c.699C>T p.F233= | Silent (SNP) | VAF 37/166 reads (22%) | catalogued as rs149457553; called by muse, mutect2, varscan2
- SLC22A12 | c.486G>A p.A162= | Silent (SNP) | VAF 36/230 reads (16%) | catalogued as rs376212424; called by muse, mutect2, varscan2
- SLCO5A1 | c.258G>A p.P86= | Silent (SNP) | VAF 63/352 reads (18%) | catalogued as rs777138818, COSV52657734; called by muse, varscan2
- SUPT20H | c.265C>T p.L89= (on ENST00000350612 / NM_001014286.3; = p.L90= on NM_017569.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/277 reads (4%) | catalogued as COSV62248618; called by muse, mutect2
- TIAM1 | c.387T>C p.T129= | Silent (SNP) | VAF 50/287 reads (17%) | catalogued as COSV99734390; called by muse, mutect2, varscan2
- TRPC3 | c.2376C>T p.F792= (on ENST00000379645 / NM_001366479.2; = p.F719= on NM_003305.2) | Silent (SNP) | VAF 45/253 reads (18%) | called by muse, mutect2, varscan2
- VAV1 | c.834C>T p.L278= | Silent (SNP) | VAF 81/214 reads (38%) | catalogued as rs748216879, COSV58380025; called by muse, mutect2, varscan2
- ZFHX4 | c.8451C>T p.D2817= | Silent (SNP) | VAF 48/333 reads (14%) | catalogued as rs746820985, COSV50496015; called by muse, mutect2, varscan2
- ZSCAN1 | c.414C>T p.F138= | Silent (SNP) | VAF 94/263 reads (36%) | catalogued as rs147151087; called by muse, mutect2, varscan2
- ATP5PF | c.-98G>T | 5'UTR (SNP) | VAF 84/371 reads (23%) | called by muse, mutect2, varscan2
- CLCN7 | c.*358G>C | 3'UTR (SNP) | VAF 26/194 reads (13%) | called by muse, mutect2, varscan2
- EHMT1 | c.1170+1440C>G | Intron (SNP) | VAF 35/263 reads (13%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+33785T>G | Intron (SNP) | VAF 36/194 reads (19%) | called by muse, mutect2
- NPEPL1 | chr20:58691207 T>G | 5'Flank (SNP) | VAF 23/239 reads (10%) | called by muse, mutect2
- PCSK6 | c.2699+57G>C | Intron (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- RNU6-1191P | chr16:81109220 G>A | 5'Flank (SNP) | VAF 48/339 reads (14%) | called by muse, mutect2, varscan2
- SLFN5 | c.-1G>C | 5'UTR (SNP) | VAF 21/124 reads (17%) | catalogued as COSV100249658; called by muse, mutect2, varscan2
